Somatic mutation profile of tumor specimen 0DUHI8 from CCDI case PBCLHB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.5 years (6,768 days).
Specimen 0DUHI8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3aa2c9b0-2d93-4826-85e9-fd68d3afec96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUHGE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da43237f-1821-40b7-bcfe-f1758a889fcf

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Nonsense Mutation 3, Silent 3, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FUT4 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs756602415; called by muse, mutect2
- HOOK1 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 77/533 reads (14%) | catalogued as COSV100968943; called by muse, mutect2, varscan2
- MARK4 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 141/467 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99488814; called by muse, mutect2, varscan2
- SEMA4D | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 167/494 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs150351780; called by muse, mutect2, varscan2
- ST8SIA1 | c.148C>G p.R50G | Missense Mutation (SNP) | VAF 143/329 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV53950500; called by muse, mutect2, varscan2
- USH2A | c.11661G>A p.W3887* | Nonsense Mutation (SNP) | VAF 30/458 reads (7%) | catalogued as COSV56415524; called by muse, mutect2
- HMCN1 | c.16049A>T p.D5350V | Missense Mutation (SNP) | VAF 180/498 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAX | c.852T>G p.Y284* | Nonsense Mutation (SNP) | VAF 138/364 reads (38%) | called by muse, mutect2, varscan2
- SAFB | c.1394A>G p.N465S | Missense Mutation (SNP) | VAF 20/733 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2
- TIPARP | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 25/339 reads (7%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.026); called by muse, mutect2
- ABCA5 | c.4740A>C p.S1580= | Silent (SNP) | VAF 53/802 reads (7%) | called by muse, mutect2
- RASL12 | c.111C>G p.T37= | Silent (SNP) | VAF 60/346 reads (17%) | catalogued as rs756506075, COSV54980966; called by muse, mutect2, varscan2
- SLC22A8 | c.1011C>T p.T337= | Silent (SNP) | VAF 24/520 reads (5%) | catalogued as rs762674610, COSV100267832, COSV60323881; called by muse, mutect2
- NARF | c.639+70G>A | Intron (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- RNF157 | c.*87G>C | 3'UTR (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
